TCGA case TCGA-G8-6906 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3f5a897d-1eaa-4d4c-8324-27ac07c90927

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Dead; Days to death: 6,425 days (17.6 years).

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Intra-abdominal lymph nodes; Site of resection or biopsy: Intra-abdominal lymph nodes; Classification of tumor: primary; Age at diagnosis: 58.2 years (21,272 days); Year of diagnosis: 1987; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Ann Arbor extranodal involvement: Yes; Sites of involvement: Lymph Node, Para-Aortic / Lymph Node, Retroperitoneal / Spleen / Other.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP; Days to treatment start: 22 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cyclophosphamide + Vincristine; Initial disease status: Progressive Disease; Regimen or line of therapy: CVP + Bleomycin; Days to treatment start: 1,257 days (3.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 2,561 days (7.0 years); Days to treatment end: 2,564 days (7.0 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Thiotepa; Initial disease status: Progressive Disease; Days to treatment start: 2,643 days (7.2 years).
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 2,646 days (7.2 years); Days to treatment end: 2,648 days (7.2 years); Treatment dose: 1,200 cGy; Course number: 1; Number of fractions: 6.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 2,656 days (7.3 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Recombinant Interleukin-2; Initial disease status: Progressive Disease; Days to treatment start: 2,930 days (8.0 years); Days to treatment end: 2,988 days (8.2 years).
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 75.7 years (27,655 days); Days to diagnosis: 6,383 days (17.5 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 6,383 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 6,425 days (17.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- CD10 (Flow Cytometry): Negative.
- CD19 (Flow Cytometry): Positive.
- Lactate Dehydrogenase 325 IU [Blood test normal range upper: 185].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59.2 kg; Height: 164.3 cm; BMI: 21.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G8-6906-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-G8-6906-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-G8-6906-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-G8-6906-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G8-6906-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: para-aortic; Lymph node involvement site: retroperitoneal.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Other Extranodal Site.
- Primary pathology: Extranodal involvment other: Spleen; Extranodal site involvement: 1.
- Tests performed: LDH level: 325; B cell genotype method: IgH Southern Blot.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: CD10 > 30%.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: Pet scan after treatment results: Not Done.
- Drug treatment 1: Pharmaceutical therapy drug name: Cytoxan; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP- Not specified.
- Drug treatment 2: Pharmaceutical therapy drug name: IL-2; Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Single Agent Therapy (please specify); Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: Cytoxan; Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: VP-16 + Cytoxan; Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: VP-16; Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: VP-16 + Cytoxan; Therapy regimen: Progression.
- Drug treatment 5: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Cytoxan; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Therapy regimen: Progression.

GDC annotations on this case (curator notes; quoted as recorded):
- Case submitted is found to be a recurrence after submission: Patient diagnosed and had prior treatment (CHOP) 7 years prior to procurement of the TCGA specimen. The TSS did confirm the TCGA tumor was a recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 6,425 days; disease-specific survival: no event (censored), 6,425 days; disease-free interval: event (new tumor event after initially disease-free), 6,383 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 6,383 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G8-6906-01A-11D-2209-01): tumor purity 0.87, ploidy 1.96, whole-genome doublings 0.
